Somatic mutation profile of tumor specimen ALCH-B200-TTP1-A (aliquot ALCH-B200-TTP1-A-2-0-D-A76N-36) from ALCHEMIST case ALCH-B200, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 72.6 years (26,519 days).
Specimen ALCH-B200-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6f64a15-d43c-4f25-bf81-69e4faad2a85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B200-NB1-A (Blood Derived Normal), aliquot ALCH-B200-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba487903-993a-469b-9836-bc00a94737cc

The open-access MAF lists 15 somatic variants for this specimen: 6 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 7, Missense Mutation 5, RNA 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRT83 | c.313C>A p.Q105K | Missense Mutation (SNP) | VAF 13/198 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs894390168; called by muse, mutect2
- SEMA5A | c.693C>G p.F231L | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV66789747, COSV66806994; called by muse, mutect2
- NLRP12 | c.2602C>A p.L868I | Missense Mutation (SNP) | VAF 15/289 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2
- SOWAHD | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, varscan2
- TGFBR1 | c.476C>G p.P159R | Missense Mutation (SNP) | VAF 16/432 reads (4%) | SIFT tolerated (0.8); PolyPhen benign (0.007); called by muse, mutect2
- ZNF606 | c.303G>T p.V101= | Splice Region (SNP) | VAF 7/70 reads (10%) | called by muse, mutect2
- ABCC11 | c.1971G>T p.L657= | Silent (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- ADAM30 | c.87T>C p.D29= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as rs1376955604; called by muse, mutect2
- CCDC62 | c.459A>G p.Q153= | Silent (SNP) | VAF 9/227 reads (4%) | catalogued as rs1165035943; called by muse, mutect2
- DNAJB5 | c.447G>A p.L149= | Silent (SNP) | VAF 5/90 reads (6%) | called by muse, mutect2
- NIPBL | c.5739C>G p.L1913= | Silent (SNP) | VAF 10/200 reads (5%) | called by muse, mutect2
- SEMG1 | c.852T>C p.N284= | Silent (SNP) | VAF 8/220 reads (4%) | called by muse, mutect2
- SERPIND1 | c.831T>C p.A277= | Silent (SNP) | VAF 22/190 reads (12%) | catalogued as rs759099484; called by muse, mutect2, varscan2
- RNF5P1 | n.133C>A | RNA (SNP) | VAF 32/296 reads (11%) | catalogued as rs944302723; called by muse, mutect2
- SPTBN4 | c.3857+972A>T | Intron (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
